Somatic mutation profile of tumor specimen C3L-01045-03 (aliquot CPT0123530009) from CPTAC case C3L-01045, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 73.5 years (26,843 days).
Specimen C3L-01045-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Temporal Cortex; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbc29c43-6626-4399-b095-e515001fb2df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01045-31 (Blood Derived Normal), aliquot CPT0124830002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/584452c6-ccd1-43fe-bcc8-d78589d37e5f

The open-access MAF lists 88 somatic variants for this specimen: 58 protein-altering or splice-affecting, 25 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 25, Frame Shift Del 2, 5'Flank 2, Splice Region 1, 3'UTR 1, Nonsense Mutation 1, Frame Shift Ins 1, 5'UTR 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 130/514 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PTEN | c.140G>A p.R47K | Missense Mutation (SNP) | VAF 60/89 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1057518425, COSV100909326, COSV64292806; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCD1 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as COSV54388070; called by muse, mutect2, varscan2
- ANKRD18B | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 99/224 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745968858; called by muse, mutect2, varscan2
- ARHGAP5 | c.3184A>G p.I1062V | Missense Mutation (SNP) | VAF 74/181 reads (41%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.625); catalogued as rs749432569; called by muse, mutect2, varscan2
- ARHGEF1 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as rs1555849283, COSV100528863; called by muse, mutect2
- ARHGEF39 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs143394421; called by muse, mutect2, varscan2
- DSG4 | c.3049G>A p.V1017I | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs186256193, COSV57392449; called by muse, mutect2, varscan2
- DYNC2H1 | c.12550C>T p.R4184C | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767920377, COSV62086491; called by muse, mutect2, varscan2
- EPHA6 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67557029, COSV67575552; called by muse, mutect2, varscan2
- GPR173 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 100/224 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.272); catalogued as rs1556805893, COSV60238576; called by muse, mutect2, varscan2
- GRB7 | c.1502G>A p.R501H | Missense Mutation (SNP) | VAF 59/189 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs767921693; called by muse, mutect2, varscan2
- HMCN1 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 90/234 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs753817944, COSV54915726; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.869A>G p.Y290C (on ENST00000354667 / NM_031243.3; = p.Y278C on NM_002137.4) | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.339); catalogued as rs1181544777, COSV61158711; called by muse, mutect2, varscan2
- HSCB | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 96/225 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs200812334; called by muse, mutect2, varscan2
- NEFM | c.2485G>A p.V829I | Missense Mutation (SNP) | VAF 158/403 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.781); catalogued as rs371207848; called by muse, mutect2, varscan2
- NOTCH2 | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 88/228 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as rs150730704; called by muse, mutect2, varscan2
- NSD2 | c.4075C>T p.R1359W | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs764374372; called by muse, mutect2, varscan2
- PTCHD4 | c.2473C>T p.R825* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | catalogued as rs144105703; called by muse, mutect2, varscan2
- QARS1 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs139730889; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RFX2 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100354038; called by muse, mutect2, varscan2
- SAMD15 | c.1648G>A p.V550I | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99375139; called by muse, mutect2
- SAP130 | c.2877G>A p.T959= | Splice Region (SNP) | VAF 20/174 reads (11%) | catalogued as rs199810314; called by muse, mutect2, varscan2
- SCRN2 | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 121/316 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as rs1300583508; called by muse, mutect2, varscan2
- SMC4 | c.586_589del p.V196Ifs*3 | Frame Shift Del (DEL) | VAF 86/225 reads (38%) | catalogued as rs1172138157; called by mutect2, pindel, varscan2
- SNTB1 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 81/197 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.641); catalogued as rs752413892, COSV67324433; called by muse, mutect2, varscan2
- SNTG2 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as rs764309007, COSV57969818; called by muse, mutect2, varscan2
- SPTLC3 | c.290G>A p.R97K | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs267605838, COSV65463320; called by muse, mutect2, varscan2
- TMEM132D | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 129/359 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs757165933, COSV70598638; called by muse, mutect2, varscan2
- TMPRSS4 | c.1176G>A p.M392I | Missense Mutation (SNP) | VAF 108/276 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as rs901021383; called by muse, mutect2, varscan2
- TREML2 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs746603843, COSV72439102; called by muse, mutect2, varscan2
- TUSC3 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 129/408 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs554205458, COSV65879924; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGT3A2 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 108/254 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs542105516, COSV99236587; called by muse, mutect2, varscan2
- AC244197.3 | c.534G>T p.Q178H | Missense Mutation (SNP) | VAF 13/329 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- ACTRT1 | c.319C>T p.L107F | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- ARAP2 | c.3673T>C p.Y1225H | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- B4GALNT4 | c.276C>A p.D92E | Missense Mutation (SNP) | VAF 107/293 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CALN1 | c.30G>T p.L10F (on ENST00000329008 / NM_001017440.3; = p.L52F on NM_031468.4) | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- CAP2 | c.1237A>T p.I413F | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- DENND2C | c.2138C>A p.A713D (on ENST00000393274 / NM_001256404.2; = p.A656D on NM_198459.4) | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH6 | c.9547T>C p.C3183R | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FEN1 | c.1065dup p.K356Qfs*10 | Frame Shift Ins (INS) | VAF 97/244 reads (40%) | called by mutect2, pindel, varscan2
- GCC2 | c.3107A>C p.E1036A | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- IL5 | c.285_288del p.K95Nfs*17 | Frame Shift Del (DEL) | VAF 82/192 reads (43%) | called by mutect2, pindel, varscan2
- KHDRBS1 | c.1256C>G p.T419S | Missense Mutation (SNP) | VAF 79/167 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYDGF | c.31G>T p.V11F | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- OGFOD3 | c.858C>A p.N286K | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PBRM1 | c.1407C>G p.I469M | Missense Mutation (SNP) | VAF 132/346 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PHKA2 | c.1460-2A>T p.X487_splice | Splice Site (SNP) | VAF 26/224 reads (12%) | called by muse, mutect2, varscan2
- PLCXD3 | c.42C>A p.D14E | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTCHD1 | c.848C>A p.A283D | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- RADX | c.2288C>A p.A763E | Missense Mutation (SNP) | VAF 83/231 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RCC1L | c.1001G>T p.G334V | Missense Mutation (SNP) | VAF 155/518 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- SAGE1 | c.857C>G p.A286G | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- SLC46A1 | c.137A>G p.Y46C | Missense Mutation (SNP) | VAF 115/300 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM164 | c.675G>T p.Q225H (on ENST00000372068 / NM_032227.4; = p.Q76H on NM_017698.2) | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2
- TOM1 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.293); called by muse, mutect2
- UPF1 | c.360A>G p.I120M | Missense Mutation (SNP) | VAF 70/205 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATG4A | c.792G>A p.A264= | Silent (SNP) | VAF 70/216 reads (32%) | catalogued as rs2294462; called by muse, mutect2, varscan2
- CAPN10 | c.387G>A p.P129= | Silent (SNP) | VAF 75/274 reads (27%) | catalogued as rs759271727; called by muse, mutect2, varscan2
- CCDC80 | c.273G>A p.P91= | Silent (SNP) | VAF 140/360 reads (39%) | catalogued as rs760498496; called by muse, mutect2, varscan2
- CDH20 | c.1080A>C p.L360= | Silent (SNP) | VAF 154/364 reads (42%) | catalogued as rs1490413105; called by muse, mutect2, varscan2
- CIT | c.729C>T p.A243= | Silent (SNP) | VAF 86/213 reads (40%) | catalogued as rs564052166; called by muse, mutect2, varscan2
- COL1A2 | c.1599T>C p.P533= | Silent (SNP) | VAF 127/588 reads (22%) | called by muse, mutect2, varscan2
- DCDC1 | c.2073G>A p.A691= | Silent (SNP) | VAF 61/175 reads (35%) | catalogued as rs372424479; called by muse, mutect2, varscan2
- DYSF | c.2652C>T p.N884= | Silent (SNP) | VAF 174/439 reads (40%) | catalogued as rs398123775; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- FAM47B | c.93G>A p.A31= | Silent (SNP) | VAF 73/188 reads (39%) | catalogued as COSV61454351; called by muse, mutect2, varscan2
- GPAT3 | c.420G>C p.R140= | Silent (SNP) | VAF 8/145 reads (6%) | called by muse, mutect2
- KPNA7 | c.132C>A p.T44= | Silent (SNP) | VAF 76/246 reads (31%) | catalogued as rs1260197464; called by muse, mutect2, varscan2
- NKX1-1 | c.1278G>A p.A426= | Silent (SNP) | VAF 44/117 reads (38%) | called by muse, mutect2, varscan2
- NR2E3 | c.132G>A p.S44= | Silent (SNP) | VAF 47/111 reads (42%) | catalogued as rs759064828, COSV58907728; called by muse, mutect2, varscan2
- NTN4 | c.615C>T p.Y205= | Silent (SNP) | VAF 58/137 reads (42%) | catalogued as rs763488072, COSV59218818, COSV59221888; called by muse, mutect2, varscan2
- OR5I1 | c.612C>T p.Y204= | Silent (SNP) | VAF 70/221 reads (32%) | catalogued as rs774747525, COSV56886443; called by muse, mutect2, varscan2
- PCDHB16 | c.939G>A p.T313= | Silent (SNP) | VAF 106/284 reads (37%) | catalogued as rs1244265805, COSV53371780; called by muse, mutect2, varscan2
- PDE5A | c.123C>T p.T41= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as rs199789323, COSV99308866; called by muse, mutect2, varscan2
- PLCH1 | c.1461G>T p.V487= (on ENST00000340059 / NM_001130960.2; = p.V499= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- PRR30 | c.678C>T p.H226= | Silent (SNP) | VAF 52/130 reads (40%) | catalogued as rs1432921105; called by muse, mutect2, varscan2
- RAX2 | c.354G>A p.L118= | Silent (SNP) | VAF 70/211 reads (33%) | catalogued as rs1409720236; called by muse, mutect2, varscan2
- RSPH6A | c.1395G>A p.T465= | Silent (SNP) | VAF 88/269 reads (33%) | catalogued as rs748324816, COSV55569808; called by muse, mutect2, varscan2
- SERPINB10 | c.1188C>T p.S396= | Silent (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- TTC6 | c.3009G>A p.L1003= | Silent (SNP) | VAF 66/191 reads (35%) | catalogued as rs371733633; called by muse, mutect2, varscan2
- UGT2A3 | c.489A>C p.A163= | Silent (SNP) | VAF 67/148 reads (45%) | called by muse, mutect2, varscan2
- ZNF469 | c.951C>T p.A317= | Silent (SNP) | VAF 122/290 reads (42%) | catalogued as rs561239255; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM124A | c.-9A>G | 5'UTR (SNP) | VAF 7/17 reads (41%) | catalogued as rs1187299694; called by muse, mutect2, varscan2
- IMPDH1 | chr7:128409927 G>A | 5'Flank (SNP) | VAF 19/57 reads (33%) | catalogued as rs748008089; called by muse, mutect2, varscan2
- KNG1 | c.*1356G>A | 3'UTR (SNP) | VAF 112/242 reads (46%) | catalogued as rs201690296; called by muse, mutect2, varscan2
- LINC01580 | chr15:93899247 C>T | 5'Flank (SNP) | VAF 71/184 reads (39%) | called by muse, mutect2, varscan2
- PRMT2 | c.654+62G>A | Intron (SNP) | VAF 28/82 reads (34%) | catalogued as rs773978142; called by muse, mutect2, varscan2
